Somatic mutation profile of tumor specimen 0DN3ST from CCDI case PBCBFB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.9 years (2,149 days).
Specimen 0DN3ST: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c404a5c8-1fa6-400c-b78c-fff73b617eba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN3R6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50d275b1-c64b-4a0c-a51e-24e1f5a324c2

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, RNA 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BLVRA | c.387G>T p.L129F | Missense Mutation (SNP) | VAF 233/559 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV55512447; called by mutect2, varscan2
- CHI3L1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs138989209; called by muse, mutect2, varscan2
- COL20A1 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 120/1017 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs547538940, COSV58922818, COSV58925999; called by muse, mutect2, varscan2
- CSNK1G2 | c.683-5C>T | Splice Region (SNP) | VAF 78/625 reads (12%) | catalogued as rs781397404; called by muse, mutect2, varscan2
- CUX1 | c.1757G>T p.R586L (on ENST00000437600 / NM_181500.4; = p.R588L on NM_001913.5) | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs140034854, COSV52944472; called by muse, mutect2, varscan2
- DNAH5 | c.3262+1G>T p.X1088_splice | Splice Site (SNP) | VAF 83/491 reads (17%) | catalogued as rs757275351; called by muse, mutect2, varscan2
- FBN1 | c.7508C>T p.T2503I | Missense Mutation (SNP) | VAF 110/772 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs749654334; called by muse, mutect2, varscan2
- GRM8 | c.2020C>G p.H674D | Missense Mutation (SNP) | VAF 147/888 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV58827252; called by muse, mutect2, varscan2
- ICE2 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs577867875; called by muse, mutect2, varscan2
- KCNH8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 120/716 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60471464; called by muse, mutect2, varscan2
- MYH14 | c.5750G>A p.R1917H | Missense Mutation (SNP) | VAF 108/722 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs1251535956, COSV51833053; called by muse, mutect2, varscan2
- SBSPON | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 67/636 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs753981711, COSV52077357; called by muse, mutect2, varscan2
- BIRC3 | c.1720C>A p.H574N | Missense Mutation (SNP) | VAF 145/393 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERICH6 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 112/868 reads (13%) | called by muse, varscan2
- KIF24 | c.2587C>T p.Q863* | Nonsense Mutation (SNP) | VAF 112/587 reads (19%) | called by muse, mutect2, varscan2
- MAP6 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 168/737 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC5AC | c.8906C>A p.T2969K | Missense Mutation (SNP) | VAF 83/579 reads (14%) | SIFT tolerated, low confidence (0.4); called by muse, mutect2, varscan2
- NUP50 | c.222_223del p.G75Ifs*3 | Frame Shift Del (DEL) | VAF 151/964 reads (16%) | called by mutect2, pindel, varscan2
- PCDHB11 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); called by muse, varscan2
- ZMIZ1 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 261/612 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- AP002748.5 | c.1249C>A p.R417= | Silent (SNP) | VAF 62/706 reads (9%) | catalogued as COSV59150788; called by muse, mutect2
- PCYT2 | c.921C>T p.H307= | Silent (SNP) | VAF 202/579 reads (35%) | catalogued as rs149977072; called by muse, mutect2, varscan2
- PRDM9 | c.2274C>T p.R758= | Silent (SNP) | VAF 215/1228 reads (18%) | called by muse, mutect2, varscan2
- UGT1A5 | c.804G>A p.P268= | Silent (SNP) | VAF 324/1180 reads (27%) | catalogued as rs371219022; called by muse, mutect2
- CLLU1 | n.861C>T | RNA (SNP) | VAF 108/805 reads (13%) | catalogued as rs1376510834; called by muse, mutect2, varscan2
- FARP1 | c.2143+653G>A | Intron (SNP) | VAF 35/205 reads (17%) | catalogued as rs1385377035; called by muse, mutect2, varscan2
- GLRX2 | chr1:193105673 G>A | 5'Flank (SNP) | VAF 117/268 reads (44%) | called by muse, mutect2, varscan2
